Somatic mutation profile of tumor specimen 0DZEHP from CCDI case PBCTUD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 21.1 years (7,703 days).
Specimen 0DZEHP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f8b54d2-cd0d-4cc4-84d1-34dfb72be1bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZEH1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63f5203f-8eb1-42ea-bd9e-fea9b2fa7b69

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Nonsense Mutation 4, Intron 3, Splice Site 2, 3'UTR 2, 5'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 640/1557 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, varscan2
- GJB2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 314/689 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs727503066, CM014710, COSV67010730; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SRCAP | c.7303C>T p.R2435* | Nonsense Mutation (SNP) | VAF 410/983 reads (42%) | catalogued as rs199469465, CM121173; ClinVar: pathogenic; called by muse, varscan2
- CHD7 | c.3463C>T p.R1155C | Missense Mutation (SNP) | VAF 834/1961 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201769233; ClinVar: uncertain significance; called by muse, varscan2
- CHD8 | c.7337C>T p.T2446M (on ENST00000646647 / NM_001170629.2; = p.T2167M on NM_020920.4) | Missense Mutation (SNP) | VAF 732/1667 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.105); catalogued as rs763909898; called by muse, varscan2
- CHD8 | c.2170G>A p.V724I (on ENST00000646647 / NM_001170629.2; = p.V445I on NM_020920.4) | Missense Mutation (SNP) | VAF 564/1348 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as rs928198790; called by muse, varscan2
- CSPG4 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 206/526 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs1490613821; called by muse, varscan2
- ENTHD1 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 353/735 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs753644902, COSV57319440; called by muse, varscan2
- GOLGA6L1 | c.1552A>G p.M518V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs760766008; called by muse, varscan2
- IGSF9B | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 437/968 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs766714994, COSV100318671; called by muse, varscan2
- KHDC3L | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 646/1415 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as rs374313878; called by muse, varscan2
- LRRN1 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 973/2116 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs375411802; called by muse, varscan2
- OLFML2B | c.949+1G>A p.X317_splice | Splice Site (SNP) | VAF 316/715 reads (44%) | catalogued as rs748357924, COSV54194970, COSV99668018; called by muse, varscan2
- QPCTL | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 162/516 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV50004715; called by muse, varscan2
- YEATS2 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 498/1172 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV100527706; called by muse, varscan2
- ABCB1 | c.1373T>A p.I458N | Missense Mutation (SNP) | VAF 192/1430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADGRB3 | c.3103del p.X1035_splice | Splice Site (DEL) | VAF 322/1162 reads (28%) | called by pindel, varscan2
- CCBE1 | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 428/966 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CDK5RAP2 | c.3147T>A p.I1049= | Splice Region (SNP) | VAF 385/1142 reads (34%) | called by muse, varscan2
- COG7 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 410/975 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KMT2D | c.14575C>T p.Q4859* | Nonsense Mutation (SNP) | VAF 540/1240 reads (44%) | called by muse, varscan2
- LHX4 | c.230G>C p.C77S | Missense Mutation (SNP) | VAF 502/1124 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- LRPAP1 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 518/1244 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- LYPD5 | c.620G>A p.C207Y (on ENST00000377950 / NM_001031749.3; = p.C164Y on NM_182573.2) | Missense Mutation (SNP) | VAF 322/1080 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MEF2C | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 593/1448 reads (41%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.986); called by muse, varscan2
- MUC19 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 670/1652 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.205); called by muse, varscan2
- PAX5 | c.536A>T p.Y179F | Missense Mutation (SNP) | VAF 438/1478 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, varscan2
- PPEF1 | c.1857C>A p.D619E | Missense Mutation (SNP) | VAF 766/844 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PSG3 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 224/2068 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.044); called by muse, varscan2
- SOX4 | c.914C>A p.S305* | Nonsense Mutation (SNP) | VAF 110/590 reads (19%) | called by muse, varscan2
- SUZ12 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 390/922 reads (42%) | called by muse, varscan2
- TBL1XR1 | c.422_423dup p.A142* | Frame Shift Ins (INS) | VAF 170/933 reads (18%) | called by pindel, varscan2
- XK | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 108/781 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.336); called by muse, varscan2
- CDH8 | c.1968T>C p.D656= | Silent (SNP) | VAF 997/2242 reads (44%) | catalogued as rs143586940, COSV54850535; called by muse, varscan2
- DHX16 | c.705G>T p.L235= | Silent (SNP) | VAF 392/894 reads (44%) | called by muse, varscan2
- ELF3 | c.810C>T p.P270= | Silent (SNP) | VAF 255/589 reads (43%) | called by muse, varscan2
- GOLGA6L1 | c.1576A>C p.R526= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1241117531; called by muse, varscan2
- NLRP8 | c.895C>T p.L299= | Silent (SNP) | VAF 512/1674 reads (31%) | called by muse, varscan2
- PEG3 | c.423C>T p.D141= | Silent (SNP) | VAF 218/892 reads (24%) | catalogued as rs755423178, COSV55631363; called by muse, varscan2
- TMEM192 | c.465G>A p.L155= | Silent (SNP) | VAF 576/1305 reads (44%) | called by muse, varscan2
- CEACAM4 | c.669+56G>T | Intron (SNP) | VAF 209/730 reads (29%) | catalogued as COSV55732956; called by muse, varscan2
- CHST5 | c.*9G>A | 3'UTR (SNP) | VAF 234/524 reads (45%) | called by muse, varscan2
- NAMPT | c.743+8dup | Intron (INS) | VAF 378/1085 reads (35%) | called by pindel, varscan2
- SCUBE2 | c.2702-90T>C | Intron (SNP) | VAF 72/246 reads (29%) | called by muse, varscan2
- SUPT7L | chr2:27663697 C>T | 5'Flank (SNP) | VAF 152/306 reads (50%) | called by muse, varscan2
- ZNF891 | c.*32_*33del | 3'UTR (DEL) | VAF 240/693 reads (35%) | called by pindel, varscan2
